Gene-level copy-number profile of specimen HCM-BROD-0097-C15-85B from HCMI case HCM-BROD-0097-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 73.5 years (26,828 days).
Specimen HCM-BROD-0097-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 15fc2f6b-d896-45a1-af2c-eafad5037336.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0097-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,743 have no estimate.
https://portal.gdc.cancer.gov/files/97dd69ae-d483-48d5-b783-0e05f5d8a311

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 150; copy number 2: 10,987; copy number 3: 25,068; copy number 4: 12,722; copy number 5: 5,903; copy number 6: 1,304; copy number 7: 1,131; copy number 8: 1,147; copy number 9: 150; copy number 10: 125; copy number 11: 134; copy number 12: 38; copy number 13: 18.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,540,049–75,590,649, 3 genes (within-gene range 0–8): AC133041.1, RPS3AP15, AC108724.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,743 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–1,780,457, 138 genes, copy number 7–11 (broad region; genes not listed).
- chr1:7,915,871–8,122,702, 8 genes, copy number 7–8: TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, ERRFI1, AL034417.2, AL034417.1.
- chr1:10,636,604–11,296,049, 21 genes, copy number 7–8: CASZ1, AL139423.1, HSPE1P24, C1orf127, CFL1P6, TARDBP, AL109811.3, MASP2, AL109811.2, SRM, EXOSC10, AL109811.1, EXOSC10-AS1, MTOR, MTOR-AS1, RNU6-537P, ANGPTL7, RNU6-291P, RPL39P6, UBIAD1, UBE2V2P3.
- chr1:143,419,625–151,993,859, 343 genes, copy number 7–10 (broad region; genes not listed).
- chr2:96,004,563–96,813,657, 24 genes, copy number 7: RN7SL210P, FAHD2CP, GPAT2, ADRA2B, ASTL, DUSP2, AC012307.1, STARD7, STARD7-AS1, TMEM127, CIAO1, SNRNP200, AC021188.1, ITPRIPL1, NCAPH, NEURL3, AC013270.1, ARID5A, KANSL3, FER1L5, LMAN2L, CNNM4, MIR3127, CNNM3-DT.
- chr2:194,344,190–194,761,435, 5 genes, copy number 9: LINC01821, AC106883.1, Metazoa_SRP, AC006196.1, LINC01790.
- chr4:68,704,600–68,951,804, 13 genes, copy number 7–9: AC147055.1, AC093720.1, AC021146.8, UGT2B10, AC021146.9, AC021146.4, AC021146.11, AC021146.2, AC021146.3, AC021146.12, AC021146.6, AC021146.1, UGT2A3.
- chr4:149,351,709–152,104,720, 39 genes, copy number 7: IQCM, AC108168.1, AC093893.1, AKIRIN2P1, RNA5SP167, RNU6-1230P, AC105343.1, DCLK2, RNU7-194P, LRBA, AC092612.1, AC110813.1, MAB21L2, ZBTB8OSP1, RNA5SP168, AK4P6, RPS3A, SNORD73B, SH3D19, SNORD73A, AC095055.1, AC104819.1, PRSS48, AC104819.2, RNU6-1282P, AC104819.3, FAM160A1-DT, FAM160A1, RN7SKP35, GATB, AC092611.1, AC107074.1, AC112242.1, AC097375.2, AC097375.1, AC097375.4, AC097375.3, RNA5SP169, LINC02273.
- chr4:152,769,354–154,491,799, 27 genes, copy number 7: TIGD4, ARFIP1, NSA2P6, FAM192BP, AC093599.2, FHDC1, AC093599.1, TRIM2, AC013477.1, RNU6-1196P, Y_RNA, ANXA2P1, MND1, RN7SL419P, TMEM131L, AC106865.2, AC106865.1, WDR45P1, TLR2, RNF175, AC020703.1, SFRP2, AC079298.3, DCHS2, AC079298.1, AC079298.2, AC110775.1.
- chr5:73,120,569–73,175,143, 4 genes, copy number 7: TMEM171, AC116345.3, AC116345.2, TMEM174.
- chr5:73,337,906–73,509,254, 9 genes, copy number 7: LINC02230, AC099522.1, FOXD1, FOXD1-AS1, LINC01385, LINC01386, AC099522.2, BTF3, FUNDC2P1.
- chr5:163,709,210–163,887,827, 4 genes, copy number 8–9: AC116917.1, RNU6-168P, AC008432.1, LSM1P2.
- chr5:172,641,263–172,819,958, 11 genes, copy number 7: NEURL1B, AC027309.2, MIR5003, AC027309.1, AC022217.2, AC022217.1, AC022217.3, DUSP1, Y_RNA, AC022217.4, AC110011.1.
- chr6:53,051,991–53,236,297, 10 genes, copy number 8–10 (within-gene range 5–10): FBXO9, AL031178.2, RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1, RNU1-136P, HMGB1P20.
- chr6:61,679,961–62,286,225, 2 genes, copy number 7 (within-gene range 5–7): KHDRBS2, AL355347.1.
- chr6:63,211,446–65,707,226, 19 genes, copy number 7 (within-gene range 6–7): FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4.
- chr6:66,093,431–66,728,904, 3 genes, copy number 7–8: NUFIP1P1, AL450336.1, RNU7-66P.
- chr7:73,005,541–73,111,140, 14 genes, copy number 13 (within-gene range 4–13): PMS2P7, Y_RNA, SPDYE8, PMS2P8, Y_RNA, AC211476.5, AC211476.3, SPDYE11, AC211476.4, Y_RNA, SPDYE9, PMS2P6, Y_RNA, SPDYE10P.
- chr8:67,043,079–71,228,629, 60 genes, copy number 7 (within-gene range 4–7): COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1.
- chr8:73,420,369–143,563,062, 983 genes, copy number 7–13 (within-gene range 4–13) (broad region; genes not listed).
- chr11:72,478,221–74,009,085, 55 genes, copy number 8–10: ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.2, AP003717.3, UCP3.
- chr11:75,759,512–76,553,025, 20 genes, copy number 8–12 (within-gene range 6–12): DGAT2, AP001922.3, AP003031.1, UVRAG-DT, UVRAG, Y_RNA, Y_RNA, PPP1R1AP1, AP003168.2, RNA5SP344, AP003168.1, AP002340.1, WNT11, AP000785.1, LINC02761, THAP12, GVQW3, Y_RNA, AP002360.1, EMSY.
- chr11:76,654,169–77,041,973, 12 genes, copy number 7–8: AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6.
- chr11:102,691,487–102,727,050, 2 genes, copy number 7: MMP27, MMP8.
- chr11:129,761,713–130,547,429, 22 genes, copy number 9: AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2, APLP2, RPL34P21, U4, ST14, ZBTB44, NDUFAF2P2, DDX18P5, RN7SL778P, ZBTB44-DT, ADAMTS8, ADAMTS15, AP004371.1, BAK1P2.
- chr12:71,007,773–71,586,310, 6 genes, copy number 7 (within-gene range 5–7): AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1.
- chr14:49,768,130–49,913,760, 11 genes, copy number 8: KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP.
- chr15:59,372,693–59,689,534, 13 genes, copy number 7 (within-gene range 3–7): FAM81A, NSA2P4, AC092868.1, Y_RNA, AC092754.2, AC092754.1, RNA5SP396, GCNT3, GTF2A2, AC092755.1, BNIP2, PIGHP1, AC092755.2.
- chr16:24,610,209–24,911,628, 4 genes, copy number 7: TNRC6A, LINC01567, AC008731.1, SLC5A11.
- chr16:25,691,959–29,698,699, 134 genes, copy number 8–13 (broad region; genes not listed).
- chr16:35,090,501–35,912,516, 72 genes, copy number 8–9 (broad region; genes not listed).
- chr16:88,234,785–88,687,278, 11 genes, copy number 7: AC138512.1, ZNF469, ZFPM1, MIR5189, AC116552.1, ZC3H18, IL17C, CYBA, MVD, SNAI3-AS1, SNAI3.
- chr18:15,196,999–15,247,997, 2 genes, copy number 8–10: AP005901.3, BNIP3P3.
- chr18:20,946,906–23,026,488, 50 genes, copy number 7–8: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr18:23,503,470–23,982,556, 8 genes, copy number 7: RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1.
- chr18:24,321,686–25,352,190, 21 genes, copy number 7: MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1.
- chr19:7,112,255–8,514,167, 73 genes, copy number 7 (broad region; genes not listed).
- chr19:22,286,441–24,163,425, 86 genes, copy number 7 (broad region; genes not listed).
- chr19:29,665,459–33,815,763, 79 genes, copy number 9–12 (broad region; genes not listed).
- chr19:34,092,561–39,943,680, 318 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 150. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
